Surgical pathology report (de-identified scan), TCGA case TCGA-60-2698, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2698-01A (Primary Tumor).

[page 1 of 2]
- #1 excision, portion of 6th right rib
#2 biopsy, middle lobe peribronchial lymph node
#3 right lower lobe
#4 excisional biopsy, lymph node #8
#5 excisional biopsy, lymph node #4

FROZEN SECTION DIAGNOSIS:

FS2: negative for metastatic disease

FS3A: free of tumor

FS3B: tumor from right lower lobe; poorly differentiated non small cell carcinoma. tumor and normal lung tissue submitted to tissue bank

GROSS DESCRIPTION:

#1 Received in formalin is a single 1.7x2.2x1.5cm. portion of grossly unremarkable rib and attached dense connective tissue and skeletal muscle. Representatives submitted in one cassette after decalcification.

#2 Received fresh is a single 1.8x1.0x0.7cm. encapsuled mass of mottled brown and black soft tissue. Externally unremarkable; cut section reveals anthracosis, but is otherwise unrevealing. Bisected and submitted in toto in one cassette; portion sent frozen submitted as FS2.

#3 Received unfixed is a 15x10x8cm. right lower lung lobe. The visceral pleural aspect over the convexity of the lobe displays diffuse erythema and focal frank subpleural hemorrhage within the postero-medial portion of the lobe. Beneath this area a large firm mass is palpated. Examination of the hilar aspect reveals similar discoloration around the hilum itself to a radius of 3cm. The hilum is otherwise grossly unremarkable. Serial thin sections through the lobe in horizontal plane reveal a 5.5x5.0x4.2cm. lobulated, well circumscribed mottled yellow white and black firm mass. This mass occupies a subhilar position within the central portion of the lobe. This tumor encroaches to within 0.2cm. of the visceral pleura near the posterior reflection of the lobe and to within 0.5cm. of the lobar hilum itself. The lobar main bronchus displays an endobronchial component. The distal portions of the postero-inferior segments of the lobe display marked bronchial mucous plugging and atelectasis. No

[page 2 of 2]
other intraparenchymal lesions are noted.

Representatives are submitted as follows:

FS3A and B-portions sent frozen

3A-true margins, bronchial and pulmonary vascular

3B-additional bronchial margin (see FS3A) and parenchymal margins

3C to 3F-tumor and hilum

3G-distal lung parenchyma, postero-inferior segment

3H-gross unremarkable lung tissue

3I to 3K-peribronchial and hilar lymph nodes (matted lymph nodes)

#4 Received in formalin is a single 1.5x0.7x0.7cm. oval encapsulated mass of yellow tan and black soft tissue. Externally unremarkable; cut section reveals a single eccentric 0.8x0.5x0.5cm. oval white cystic mass. Bisected and submitted in toto in one cassette.

#5 Received in formalin is a single 0.4x0.3x0.3cm. oval encapsulated mass and brown soft tissue and attached fibroadipose measuring 0.7x0.5x0.4cm. overall. Externally unremarkable; cut section is unrevealing. Bisected and submitted in toto in one cassette.

Total number of blocks: 18

DIAGNOSIS:

- 2) MIDDLE LOBE, BRONCHIAL NODE: ANTHRACOSIS (NEGATIVE FOR TUMOR)
- 3) LOWER LOBE OF RIGHT LUNG, RESECTION: MODERATELY TO POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA OF LOWER LOBE OF RIGHT LUNG WITH METASTASIS TO PERIBRONCHIAL AND HILAR LYMPH NODES (BRONCHIAL MARGIN-NEGATIVE FOR TUMOR)
- 4) LYMPH NODE #8: POSITIVE FOR METASTATIC SQUAMOUS CELL CARCINOMA
- 5) LYMPH NODE #4: ONE LYMPH NODE, NEGATIVE FOR TUMOR.

In #3 tumor shows areas of necrosis, slide 3C-there is transition from benign to neoplastic squamous epithelium. Prominent invasion seen in #3I. Remainder of lung parenchyma shows congestion with no evidence of pneumonic process.

Source: NCI Genomic Data Commons file 09fc6f01-e981-4e91-9110-55e28b4b443b (TCGA-60-2698.FD7AAB4D-F043-48E5-AF10-789C56DEBC41.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).